Somatic mutation profile of tumor specimen 0E1SCG from CCDI case PBCVVF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1SCG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 607c7244-8507-4be2-9509-18d8564109ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1SBV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/564cdb04-bfcd-4a87-8524-d49f7fcd021e

The open-access MAF lists 30 somatic variants for this specimen: 17 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 10, Frame Shift Del 2, 5'UTR 2, Frame Shift Ins 1, Intron 1, Splice Site 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAR | c.1798C>A p.Q600K | Missense Mutation (SNP) | VAF 141/455 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.081); catalogued as CM051379; called by muse, mutect2, varscan2
- ANPEP | c.2386G>A p.V796I | Missense Mutation (SNP) | VAF 164/511 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.246); catalogued as rs369616479; called by muse, mutect2, varscan2
- CDKL5 | c.2435G>T p.S812I | Missense Mutation (SNP) | VAF 59/976 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV101184202; called by muse, mutect2
- FER1L6 | c.1716G>T p.L572F | Missense Mutation (SNP) | VAF 218/1689 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV67550902; called by muse, mutect2, varscan2
- RYR3 | c.10545G>T p.W3515C (on ENST00000389232; = p.W3516C on NM_001036.6) | Missense Mutation (SNP) | VAF 411/1298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66777492; called by muse, mutect2, varscan2
- SLC12A3 | c.2768G>C p.G923A (on ENST00000563236 / NM_001126108.2; = p.G932A on NM_000339.3) | Missense Mutation (SNP) | VAF 206/623 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV52637679; called by muse, mutect2, varscan2
- ZBED1 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 46/614 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100585641; called by muse, mutect2
- DNAH3 | c.9434C>A p.A3145E | Missense Mutation (SNP) | VAF 135/346 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- NCAPG2 | c.410A>C p.E137A | Missense Mutation (SNP) | VAF 210/797 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- NRK | c.175C>G p.R59G | Missense Mutation (SNP) | VAF 82/736 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NTN5 | c.915C>A p.C305* | Nonsense Mutation (SNP) | VAF 89/233 reads (38%) | called by muse, mutect2, varscan2
- OSBPL3 | c.1964del p.N655Tfs*18 | Frame Shift Del (DEL) | VAF 144/523 reads (28%) | called by mutect2, varscan2
- SCN2A | c.986dup p.L329Ffs*6 | Frame Shift Ins (INS) | VAF 306/1031 reads (30%) | called by mutect2, varscan2
- TDGF1 | c.17T>G p.M6R | Missense Mutation (SNP) | VAF 214/525 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRIM28 | c.2107-4G>T | Splice Region (SNP) | VAF 49/229 reads (21%) | called by muse, mutect2, varscan2
- VPS33A | c.1610-1G>T p.X537_splice | Splice Site (SNP) | VAF 37/287 reads (13%) | called by muse, mutect2, varscan2
- ZC3H7B | c.514_515del p.K172Efs*13 | Frame Shift Del (DEL) | VAF 122/302 reads (40%) | called by mutect2, varscan2
- CHRNB4 | c.768G>T p.L256= | Silent (SNP) | VAF 48/782 reads (6%) | called by muse, mutect2
- JMJD4 | c.1068G>A p.E356= | Silent (SNP) | VAF 205/429 reads (48%) | called by muse, mutect2, varscan2
- LIPI | c.189G>A p.E63= | Silent (SNP) | VAF 417/950 reads (44%) | catalogued as COSV60715934; called by muse, mutect2, varscan2
- MAP1S | c.1122C>T p.R374= | Silent (SNP) | VAF 52/147 reads (35%) | catalogued as rs777612522; called by muse, mutect2, varscan2
- MROH2A | c.3318C>T p.A1106= | Silent (SNP) | VAF 173/594 reads (29%) | called by mutect2, varscan2
- NDST2 | c.2373C>T p.I791= | Silent (SNP) | VAF 24/496 reads (5%) | called by muse, mutect2
- PSG9 | c.1206C>A p.G402= | Silent (SNP) | VAF 58/742 reads (8%) | called by muse, mutect2
- RECQL4 | c.1176T>G p.G392= | Silent (SNP) | VAF 123/924 reads (13%) | catalogued as rs1054027953, COSV52878448; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEPTIN6 | c.162C>A p.G54= | Silent (SNP) | VAF 72/379 reads (19%) | called by muse, mutect2, varscan2
- SPRED3 | c.144C>T p.Y48= | Silent (SNP) | VAF 67/241 reads (28%) | catalogued as rs912063370; called by muse, mutect2, varscan2
- ALPI | c.68-29G>T | Intron (SNP) | VAF 91/256 reads (36%) | called by muse, varscan2
- HNRNPA2B1 | c.-7G>A | 5'UTR (SNP) | VAF 198/750 reads (26%) | catalogued as rs767779702; called by muse, mutect2, varscan2
- MED13 | c.-69_-66del | 5'UTR (DEL) | VAF 20/63 reads (32%) | catalogued as rs990387164; called by mutect2, varscan2
